Surgical pathology report (de-identified scan), TCGA case TCGA-73-A9RS, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-73-A9RS-01A (Primary Tumor).

[page 1 of 4]
TSS '
Surg Date

SPECIMENS:

- A. 4R LYMPH NODE
- B. ADDITIONAL 4R LYMPH NODE
- C. 4R LYMPH NODE #3
- D. LEVEL 7 LYMPH NODE
- E. 4R LYMPH NODE #4
- F. PERI BRONCHIAL BIOPSY (RIGHT SIDE)
- G. PORTIONS OF 8TH RIB
- H. PORTION OF 7TH RIB
- I. RIGHT LUNG WITH MID CHEST WALL
- J. LEVEL 8 LN

SPECIMEN(S):

- A. 4R LYMPH NODE
- B. ADDITIONAL 4R LYMPH NODE
- C. 4R LYMPH NODE #3
- D. LEVEL 7 LYMPH NODE
- E. 4R LYMPH NODE #4
- F. PERI BRONCHIAL BIOPSY (RIGHT SIDE)
- G. PORTIONS OF 8TH RIB
- H. PORTION OF 7TH RIB
- I. RIGHT LUNG WITH MID CHEST WALL
- J. LEVEL 8 LN

DIAGNOSIS:

- A. LYMPH NODE, 4R, BIOPSY:
- FRAGMENTS OF LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- B. LYMPH NODE, ADDITIONAL 4R, BIOPSY:
- FRAGMENTS OF LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- C. LYMPH NODE, 4R #3, BIOPSY:
- FRAGMENTS OF LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- D. LYMPH NODE, LEVEL 7, BIOPSY:
- ONE FRAGMENT OF LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- E. LYMPH NODE, 4R #4, BIOPSY:
- FRAGMENTS OF LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)
- F. PERI BRONCHIAL (RIGHT SIDE), BIOPSY:
- NO EVIDENCE OF CARCINOMA
- G. PORTIONS OF 8TH RIB, RESECTION:
- PENDING DECALCIFICATION
- H. PORTION OF 7TH RIB, RESECTION:
- PENDING DECALCIFICATION
- I. RIGHT LUNG WITH MID CHEST WALL, PNEUMONECTOMY:
- INVASIVE MODERATELY DIFFERENTIATED ADENOCARCINOMA, INVADING INTO CHEST WALL
- 9.2 CM IN GREATEST DIMENSION
- BRONCHIAL MARGIN IS NEGATIVE CARCINOMA
- SOFT TISSUE RESECTION MARGIN IS NEGATIVE FOR CARCINOMA
- BONE RESECTION MARGINS ARE NEGATIVE FOR CARCINOMA
- NINETEEN PERIBRONCHIAL LYMPH NODES, NEGATIVE FOR CARCINOMA (0/19)
- SEE SYNOPSIS REPORT
- J. LYMPH NODE, LEVEL 8, BIOPSY:

ICD 03

Adenocarcinoma NOS 8480/3
Site R Lung, upper lobe C34.1
9/3/14

[page 2 of 4]
- ONE FRAGMENT OF LYMPH NODE, NEGATIVE FOR CARCINOMA (0/1)

SYNOPTIC REPORT - LUNG

Specimens Involved

Specimens: A: 4R LYMPH NODE

B: ADDITIONAL 4R LYMPH NODE

C: 4R LYMPH NODE #3

D: LEVEL 7 LYMPH NODE

E: 4R LYMPH NODE #4

F: PERI BRONCHIAL BIOPSY (RIGHT SIDE)

G: PORTIONS OF 8TH RIB

H: PORTION OF 7TH RIB

I: RIGHT LUNG WITH MID CHEST WALL

J: LEVEL 8 LN

Surgical Procedure: Pneumonectomy

Laterality: Right

Tumor Site: Upper lobe

Tumor Location: Peripheral

Tumor Size: Greatest diameter: 9.2cm

WHO CLASSIFICATION

Adenocarcinoma

Histologic Grade: G2: Moderately differentiated

Angiolymphatic Invasion: Absent

Bronchial Margins: Bronchial margins uninvolved

Visceral Pleural Involvement: Present (pT2)

Satellite Tumor(s): Absent

Lymph Node Involvement: N1: Ipsilateral Hilar and/or Peribronchial (levels 10-14)

Negative 0 / 19

N2: Ipsilateral Mediastinal and/or Subcarinal (Levels 1-9)

Negative 0 / 6

Non-Neoplastic Lung: Emphysematous changes

Hematoma (1.3 cm in greatest dimension) in the right lower lobe

Additional Pathologic Findings: Inflammation

Type: Chronic inflammation

Pathological Staging (pTNM): pT 3 N 0 M x

Pathological staging is based on the AJCC Cancer Staging Manual, 7th Edition

GROSS DESCRIPTION:

A. 4R LYMPH NODE

Received fresh labeled with the patient's identification and designated "4R lymph node" are two fragments of red-tan soft tissue measuring 0.6 x 0.3 x 0.2 cm and 0.5 x 0.3 x 0.2 cm. Entirely submitted for frozen section, FSA.

B. ADDITIONAL 4R LYMPH NODE

Received fresh labeled with the patient's identification and designated "additional 4R lymph node" are multiple (approximately 5) fragments of red-tan soft tissue ranging from 0.4 x 0.3 x 0.2 cm up to 0.9 x 0.3 x 0.2 cm. Entirely submitted for frozen section, FSB.

C. 4R LYMPH NODE #3

Received fresh labeled with the patient's identification and designated "4R lymph node #3" are two fragments of red-tan soft tissue measuring 0.1 and 0.8 cm in greatest dimension. Entirely submitted for frozen section, FSC.

D. LEVEL 7 LYMPH NODE

Received fresh labeled with the patient's identification and designated "level 7" is a fragment of red-tan soft tissue measuring 0.6 cm in greatest dimension. Entirely submitted for frozen section, FSD.

E. 4R LYMPH NODE #4

Received fresh labeled with the patient's identification and designated "4R lymph node #4" are multiple (approximately 4) fragments of red-tan soft tissue ranging from 0.3 up to 0.9 cm in greatest dimension. Entirely submitted for frozen section, FSE.

F. PERIBRONCHIAL BIOPSY (RIGHT SIDE)

Received fresh labeled with the patient's identification and designated "peribronchial biopsy right side" is a fragment of red-tan soft tissue measuring 0.5 x 0.1 by less than 0.1 cm. Entirely submitted for frozen section, FSF.

[page 3 of 4]
G. PORTION OF 8TH RIB

Received in formalin labeled with the patient's identification and designated "portion of eighth rib" are two fragments of unoriented bone measuring 4 x 2.5 x 1.5 cm in aggregate. Representatively submitted in G1 for decalcification.

H. PORTION OF 7th RIB

Received in formalin labeled with the patient's identification and designated "portion of seventh rib" are two fragments of unoriented bone measuring 3.9 x 3 x 1.3 cm in aggregate. Representatively submitted in H1 for decalcification.

I. RIGHT LUNG WITH MID CHEST WALL

Received fresh and subsequently fixed in formalin labeled with the patient's identification and designated "right lung with mid chest wall" is an oriented (suture marks sixth rib) right pneumonectomy specimen with en bloc chest wall resection of ribs (3) and intercostal soft tissue. The right lobe, 20 x 18 x 8.5 cm, middle lobe (collapsed), 10.5 x 9.2 x 2 cm, and lower lobe 11 x 10.8 x 5 cm. The attached chest wall consisting of three ribs, 9.3 x 6.2 x 1.5 cm, collectively, and portion of intercostal soft tissue, 7 x 3 x 1 cm. Ink code: Right upper lobe-blue, right mid lobe-orange, right lower lobe- black, lateral bone margin-green, anterior bone margin-yellow, posterior tissue (possible upper lobe lung)-red. The pleural surface of the upper lobe shows multiple bullae, ranging from 0.5 up to 2 cm in greatest dimension. The superior portion of the upper lobe shows an ill-defined, nodular, firm white tan, centrally necrotic mass grossly adherent to the chest wall, measuring approximately 9.2 x 6.5 x 5.4 cm, located 6.5 cm from the bronchial margin, extending to the lateral and posterior soft tissue margins (green ink, red-ink). The remainder of the upper lobe is sectioned to show deep red, consolidated, focally fibrotic lung parenchyma. The middle lobe is sectioned to reveal deep red, consolidated lung parenchyma. No lesions or nodules are grossly appreciated in the middle lobe. The right lower lobe (apex) shows an ill-defined, firm, red-tan, hemorrhagic lesion, 1.3 x 1 x 0.9 cm, located approximately 16.5 cm from the bronchial margin. The remainder of the right lower lobe shows consolidated, focally fibrotic lung parenchyma. Gross photograph is taken. A portion of the specimen is submitted for tissue procurement. Representatively submitted:

FSI1: Shaved bronchial margin

I2: Posterior soft tissue margin

I3-I6: Right upper lobe, mass, pleural surface, lateral soft tissue posterior to ribs

I7: Anterior bone margin

I8-I10: One continuous section mass, ribs, lateral bone margin

I11: Vascular margin

I12-I13: Lower lobe, lesion and pleura

I14: Lower lobe, random section

I15-I16: Random sections middle lobe

I17: Additional sections, mass, upper lobe, posterior

I18-I19: Random sections, upper lobe

I20-I23: Multiple possible lymph nodes, upper lobe

I24-I25: One hilar lymph node, upper lobe

I26: Possible lymph nodes, lower lobe

J. LEVEL 8 LYMPH NODE

Received in formalin labeled with the patient's identification and designated "level 8 lymph node" is a fragment of tan possible lymphoid tissue measuring 2.3 x 0.7 x 0.7 cm. The specimen is sectioned, entirely submitted, J1.

CLINICAL HISTORY:

None Given

PRE-OPERATIVE DIAGNOSIS:

Right upper lobe ca

FROZEN SECTION INTRAOPERATIVE REPORT:

FSA: Lymph node, 4R, biopsy: Negative

FSB: Lymph node, additional 4R, biopsy: Negative

FSC: Lymph node, 4R #3, biopsy: Negative

FSD: Lymph node, level 7, biopsy: Negative

FSE: Lymph node, 4R #4, biopsy: Negative

Diagnoses called to Dr. at (A), (B), (C, D), (E) by Dr.

FSF: Soft tissue, peribronchial biopsy, right: Lung tissue with inflammation, no tumor seen

Diagnosis called to Dr. at Dr. FSI: Right lung and mid chest wall, resection: Bronchial margin negative

[page 4 of 4]
Diagnosis called to Dr. at _____ by Dr. _____

Gross Dictation: M.S.,
Microscopic/Diagnostic Dictation: M.S.
Final Review: M.D., Pathologist
Final Review: M.D., Pathologist
Final Review: M.D., Pathologist
Final Review: M.D., Pathologist
Final: M.D., Pathologist
Addendum: M.D., Pathologist
Addendum Final: M.D., Pathologist

Source: NCI Genomic Data Commons file 1fb8037b-20ae-4eaf-9c68-1a5127b27f93 (TCGA-73-A9RS.7E029394-80EC-4B53-829E-8F1DA476D648.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).